Somatic mutation profile of tumor specimen TCGA-A6-2684-01C (aliquot TCGA-A6-2684-01C-08D-A270-10) from TCGA case TCGA-A6-2684, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 75.9 years (27,708 days).
Specimen TCGA-A6-2684-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed7e9b2e-431a-4d04-971d-452d8abeffe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2684-10A (Blood Derived Normal), aliquot TCGA-A6-2684-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad65f362-167c-437e-a7ea-3140621ecda7

The open-access MAF lists 110 somatic variants for this specimen: 79 protein-altering or splice-affecting, 31 silent.
By variant classification: Missense Mutation 69, Silent 31, Nonsense Mutation 3, Frame Shift Ins 3, In Frame Del 1, Splice Region 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1620dup p.Q541Tfs*19 | Frame Shift Ins (INS) | VAF 83/203 reads (41%) | catalogued as rs1131691555, CI040932, CI106503, COSV57342389; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 40/183 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs397507512, CM030494, CM056378, COSV61006422; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSL5 | c.1879G>A p.G627R (on ENST00000354273; = p.G683R on NM_016234.3) | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100634846; called by muse, mutect2, varscan2
- ANKRD30A | c.3083G>T p.R1028I (on ENST00000611781; = p.R972I on NM_052997.2) | Missense Mutation (SNP) | VAF 92/542 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100654575; called by muse, mutect2, varscan2
- CAPG | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs987498288, COSV99809651; called by muse, mutect2, varscan2
- CCDC17 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1326750378, COSV51973854; called by muse, mutect2, varscan2
- CDH4 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1035268864, COSV64646564; called by muse, mutect2, varscan2
- CLEC5A | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs151000385, COSV101407806; called by muse, mutect2, varscan2
- COL2A1 | c.3003G>A p.S1001= | Splice Region (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100477014; called by muse, mutect2, varscan2
- CSMD1 | c.1693G>T p.V565F (on ENST00000520002; = p.V564F on NM_033225.6) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59300299, COSV59359418; called by muse, mutect2, varscan2
- DDX39B | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63331300; called by muse, mutect2
- DMPK | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.914); catalogued as rs373703629, COSV52176405; called by muse, mutect2, varscan2
- DNAH11 | c.9458C>G p.T3153S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100181312; called by muse, mutect2, varscan2
- DNAH7 | c.10376G>T p.S3459I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.405); catalogued as COSV100418091; called by muse, mutect2, varscan2
- DNER | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs549129843, COSV59159704, COSV59170885; called by muse, mutect2, varscan2
- EPX | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs985130173; called by muse, mutect2
- EXOC6B | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs755302023, COSV55564876; called by muse, mutect2, varscan2
- FAM170A | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs775441770, COSV58926608; called by muse, mutect2, varscan2
- FAM9A | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.923); catalogued as COSV101121378; called by muse, mutect2, varscan2
- FAN1 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100756118; called by muse, varscan2
- FAT4 | c.2739C>A p.F913L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.133); catalogued as COSV67902103; called by muse, mutect2, varscan2
- FMO3 | c.1333C>G p.P445A | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV63007137; called by muse, mutect2, varscan2
- FOLR3 | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100281896; called by muse, mutect2, varscan2
- FRMD6 | c.688G>A p.A230T (on ENST00000344768 / NM_001267046.2; = p.A222T on NM_152330.4) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs374236968; called by muse, mutect2, varscan2
- GALNS | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV99243531; called by muse, mutect2, varscan2
- KLHL34 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs914654948, COSV101070016; called by muse, mutect2, varscan2
- LDOC1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.172); catalogued as COSV65159498; called by muse, mutect2, varscan2
- LRRK1 | c.6034C>A p.R2012S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99443715; called by mutect2, varscan2
- MAN1A2 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100741090; called by muse, mutect2, varscan2
- MAT2A | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM150092, COSV99290261; called by muse, mutect2, varscan2
- MCTS1 | c.430T>C p.C144R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV64892953; called by muse, mutect2, varscan2
- MED15 | c.1814C>T p.P605L (on ENST00000263205 / NM_001003891.3; = p.P565L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53034231; called by muse, mutect2, varscan2
- MIA3 | c.1580A>T p.D527V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV100719570; called by muse, mutect2, varscan2
- MICAL3 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs755451788, COSV99263158; called by muse, mutect2, varscan2
- MKNK2 | c.655-1G>A p.X219_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99170456; called by muse, mutect2, varscan2
- MPP4 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772583255, COSV59628629; called by muse, mutect2, varscan2
- N4BP2L2 | c.1517C>G p.T506S | Missense Mutation (SNP) | VAF 160/526 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57230522; called by muse, mutect2, varscan2
- NOS1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs80348085, COSV57606077; called by muse, mutect2, varscan2
- OCA2 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 87/395 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769550106, COSV62353421, COSV62356115; called by muse, mutect2, varscan2
- OR5D14 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs200877014, COSV59455703; called by muse, mutect2, varscan2
- OR6T1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140103246, COSV58305755, COSV58309700; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDH11X | c.3455G>T p.C1152F | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100015987; called by muse, mutect2, varscan2
- PCDHA12 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56553142; called by muse, mutect2
- PCDHA7 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.336); catalogued as COSV65343999; called by muse, mutect2, varscan2
- PHF20L1 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs375482501; called by muse, mutect2, varscan2
- PLXNA1 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1395349765, COSV99302888; called by muse, mutect2, varscan2
- PPARGC1B | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1199093107, COSV100495276; called by muse, mutect2
- PWWP3A | c.985G>A p.G329R (on ENST00000627377; = p.G328R on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs767705392, COSV100262320; called by muse, mutect2
- RHCE | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as rs754954217, COSV53800579; called by muse, mutect2, varscan2
- RHO | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs201008735, COSV56214488; called by mutect2, varscan2
- RIOX2 | c.849C>G p.D283E | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV57725087; called by muse, mutect2, varscan2
- SETDB1 | c.2828C>T p.T943I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs966900297, COSV99646030; called by muse, mutect2, varscan2
- SHROOM2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254465222, COSV101099156; called by muse, mutect2, varscan2
- SPAG6 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs918860729, COSV57620478; called by muse, mutect2, varscan2
- SPTY2D1 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100311885; called by muse, mutect2, varscan2
- SUCLA2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as COSV66222466; called by muse, mutect2
- TBX3 | c.126del p.A43Rfs*2 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs746244654; called by mutect2, pindel, varscan2
- TCF12 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 54/179 reads (30%) | catalogued as COSV51003399, COSV51030204; called by muse, mutect2, varscan2
- TIAM1 | c.3880T>C p.F1294L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99739570; called by muse, mutect2, varscan2
- TMEM47 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as COSV52063432; called by muse, mutect2, varscan2
- TMOD2 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as rs779836040, COSV51044039, COSV51044309; called by muse, mutect2, varscan2
- TNRC6B | c.1516G>T p.V506F | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs1412700883, COSV57309595; called by muse, mutect2, varscan2
- TOGARAM1 | c.1224C>A p.F408L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100753333; called by muse, mutect2, varscan2
- TPD52L1 | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59194389; called by muse, mutect2, varscan2
- TTN | c.78193G>A p.E26065K (on ENST00000591111; = p.E18641K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | PolyPhen benign (0.046); catalogued as rs72648217, COSV59954756; called by muse, mutect2, varscan2
- WBP1L | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs964843862, COSV64009303; called by muse, varscan2
- ZHX2 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs766810365, COSV100074047; called by muse, mutect2, varscan2
- ZNF512 | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100179487; called by muse, mutect2, varscan2
- ZRANB1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV62844246; called by muse, mutect2, varscan2
- ZXDB | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs751291946, COSV100886087, COSV100886101; called by mutect2, varscan2
- CENPE | c.3769A>G p.S1257G | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- ELP2 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- NBEAL1 | c.6215dup p.N2072Kfs*10 | Frame Shift Ins (INS) | VAF 34/100 reads (34%) | called by mutect2, varscan2
- NDST4 | c.928_930del p.D310del | In Frame Del (DEL) | VAF 14/73 reads (19%) | called by pindel, varscan2
- ST6GAL1 | c.548G>T p.R183M | Missense Mutation (SNP) | VAF 3/46 reads (7%) | PolyPhen possibly damaging (0.704); called by muse, mutect2
- TGIF1 | c.419_422dup p.S142Vfs*61 (on ENST00000330513 / NM_001374396.1; = p.S162Vfs*61 on NM_003244.4) | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- ASB9 | c.690T>C p.A230= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV100995601; called by muse, mutect2, varscan2
- ATOH7 | c.267C>T p.I89= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV101028540; called by muse, mutect2, varscan2
- ATP4A | c.2697G>A p.A899= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs200535073, COSV52865580; called by muse, mutect2, varscan2
- C5orf49 | c.279G>A p.P93= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs368114686; called by muse, mutect2, varscan2
- CDH11 | c.27C>T p.A9= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs200930494, COSV51781373; called by muse, mutect2, varscan2
- CES3 | c.1581G>A p.L527= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100310078; called by muse, mutect2, varscan2
- CLCN5 | c.210G>A p.S70= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as rs376292808, COSV100260449; called by muse, mutect2, varscan2
- CLDN19 | c.414G>A p.S138= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs370124717; called by muse, mutect2, varscan2
- CSAG2 | c.348C>T p.P116= | Silent (SNP) | VAF 153/712 reads (21%) | catalogued as rs1259270518; called by muse, mutect2, varscan2
- CUX2 | c.4191G>A p.S1397= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs745631840, COSV99920993; called by muse, mutect2, varscan2
- DUOXA2 | c.450G>T p.L150= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- EIF4G1 | c.4431G>A p.T1477= (on ENST00000346169 / NM_198241.3; = p.T1282= on NM_004953.5) | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs778504953, COSV100072387; called by muse, mutect2, varscan2
- FMN2 | c.3528G>A p.P1176= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs183336748, COSV60445930; called by muse, mutect2, varscan2
- FOXC2 | c.1323G>A p.A441= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs541894945, COSV100234427; called by muse, mutect2, varscan2
- HFM1 | c.2631G>A p.L877= | Silent (SNP) | VAF 53/210 reads (25%) | catalogued as COSV99647004; called by muse, mutect2, varscan2
- LRIT3 | c.1113G>A p.P371= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs181208057, COSV59986649; called by muse, mutect2, varscan2
- MCM3AP | c.459G>A p.V153= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- MYO18B | c.7614C>T p.G2538= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs373074703; called by muse, mutect2, varscan2
- NPLOC4 | c.288C>T p.G96= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs999612410, COSV58620484; called by muse, mutect2, varscan2
- NPM3 | c.54G>A p.T18= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100761987; called by muse, mutect2
- NPNT | c.648C>T p.D216= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs367957343, COSV59753190; called by muse, mutect2
- NTRK3 | c.1824C>T p.G608= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs376552616; called by muse, mutect2, varscan2
- NUCKS1 | c.204C>G p.T68= | Silent (SNP) | VAF 69/301 reads (23%) | catalogued as COSV100900817; called by muse, mutect2, varscan2
- NUDT11 | c.477G>A p.S159= | Silent (SNP) | VAF 53/284 reads (19%) | catalogued as rs1557326605, COSV101047068; called by muse, mutect2, varscan2
- OSMR | c.1413T>C p.V471= | Silent (SNP) | VAF 66/256 reads (26%) | catalogued as COSV99953900; called by muse, mutect2, varscan2
- PRR22 | c.702G>T p.L234= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV57833925; called by muse, mutect2, varscan2
- RSPH6A | c.945C>T p.G315= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs778223516, COSV99680178; called by muse, mutect2, varscan2
- SCN1A | c.135C>T p.D45= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as rs201985242; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SNX8 | c.366C>T p.H122= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99771229; called by muse, mutect2, varscan2
- VCX2 | c.414C>T p.T138= | Silent (SNP) | VAF 38/256 reads (15%) | catalogued as rs757658111, COSV57704763; called by muse, mutect2, varscan2
- ZNF536 | c.3144G>A p.A1048= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1280150294, COSV62832577; called by muse, mutect2, varscan2
